Surgical pathology report (de-identified scan), TCGA case TCGA-27-1834, project TCGA-GBM (Glioblastoma Multiforme), tissue source site Milan - Italy, Fondazione IRCCS Instituto Neuroligico C. Besta, specimen TCGA-27-1834-01A (Primary Tumor).

Ref. Number

TCGA-27--1834

Gender

Birth date

Tumor site

Left temporo-mesial

Histological diagnosis

Glioblastoma multiforme

Source: NCI Genomic Data Commons file eef9ca18-c10d-4f0c-afe8-e018166fb55d (TCGA-27-1834.AE312505-E73D-44C5-A3DF-4096FADA821B.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).